Somatic mutation profile of tumor specimen TCGA-28-5215-01A (aliquot TCGA-28-5215-01A-01D-1486-08) from TCGA case TCGA-28-5215, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.1 years (22,686 days).
Specimen TCGA-28-5215-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a42e4a06-93c9-45f7-af9b-8f57b817314c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5215-10A (Blood Derived Normal), aliquot TCGA-28-5215-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5d8e2ad-ee3d-4a33-95ce-a6facf515968

The open-access MAF lists 36 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Nonsense Mutation 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT17 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 108/338 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs28928897, CM012143, CM970840, COSV60860507; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 51/92 reads (55%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3328C>T p.R1110C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1217621780, COSV65891218; called by muse, mutect2, varscan2
- ANK1 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs564238506, COSV55878648; called by muse, mutect2, varscan2
- ATP6AP1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs782737307, COSV63895538; called by muse, mutect2, varscan2
- ATP6V0D2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs769025984, COSV53414107; called by muse, mutect2, varscan2
- BCAR3 | c.2171T>C p.F724S | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.191); catalogued as COSV53074083; called by muse, mutect2, varscan2
- CABIN1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54077034, COSV54080346; called by muse, mutect2, varscan2
- DCX | c.374A>C p.Y125S | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57567999, COSV57571630; called by muse, mutect2, varscan2
- EPB41L3 | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 114/355 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59449421; called by muse, mutect2, varscan2
- HELZ | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62377518; called by muse, mutect2, varscan2
- INPP5D | c.3008C>T p.T1003M (on ENST00000445964 / NM_001017915.3; = p.T1002M on NM_005541.5) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs142742228, COSV64036470; called by muse, mutect2
- IRF6 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs750021967, COSV54213726; called by muse, mutect2
- LRP1 | c.4357G>A p.A1453T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV54506340; called by muse, mutect2, varscan2
- MFSD12 | c.761C>G p.T254S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747397118, COSV61535182, COSV61535907, COSV61536673; called by muse, mutect2, varscan2
- MYH2 | c.3194T>A p.L1065* | Nonsense Mutation (SNP) | VAF 96/149 reads (64%) | catalogued as COSV55435409; called by muse, mutect2, varscan2
- OR5D16 | c.550T>C p.S184P | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.067); catalogued as COSV65721631; called by muse, mutect2, varscan2
- PNPLA2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1222759400, COSV60744032; called by muse, mutect2, varscan2
- SLC30A4 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as rs1333330669, COSV56005572, COSV56005581; called by muse, mutect2, varscan2
- ST6GAL2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | PolyPhen benign (0.16); catalogued as COSV64527534; called by muse, mutect2
- TRIML2 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 118/398 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58715512; called by muse, mutect2
- UVRAG | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as COSV62103104; called by muse, mutect2
- VPS18 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs201577141, COSV55029636; called by muse, mutect2, varscan2
- YY2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 150/457 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV63411172; called by muse, mutect2, varscan2
- ZNF630 | c.900C>G p.F300L | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52095801, COSV52096700; called by muse, mutect2, varscan2
- AC004593.2 | c.462C>T p.A154= | Silent (SNP) | VAF 129/387 reads (33%) | catalogued as COSV56090452; called by muse, mutect2, varscan2
- ASB4 | c.75A>G p.L25= | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as COSV57507742; called by muse, mutect2, varscan2
- FNDC1 | c.3837G>A p.P1279= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs757619264, COSV51935356; called by muse, mutect2, varscan2
- OR6S1 | c.42C>T p.F14= | Silent (SNP) | VAF 181/284 reads (64%) | catalogued as rs747004005, COSV57837515; called by muse, mutect2, varscan2
- RACGAP1 | c.1311C>G p.R437= | Silent (SNP) | VAF 120/318 reads (38%) | catalogued as COSV56698999; called by muse, mutect2, varscan2
- SHCBP1 | c.1911G>A p.G637= | Silent (SNP) | VAF 118/276 reads (43%) | catalogued as rs1399993577, COSV57647098; called by muse, mutect2, varscan2
- SI | c.3909T>C p.N1303= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV52273129, COSV52290497; called by muse, mutect2, varscan2
- SIM1 | c.27G>A p.A9= | Silent (SNP) | VAF 173/472 reads (37%) | catalogued as rs747311520, COSV53489112; called by muse, mutect2, varscan2
- TMEM132D | c.1347C>T p.A449= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs189348668; called by muse, mutect2, varscan2
- TRIM71 | c.2606A>G p.*869= | Silent (SNP) | VAF 90/270 reads (33%) | catalogued as COSV67470594; called by muse, varscan2
- LPAL2 | n.3G>A | RNA (SNP) | VAF 124/444 reads (28%) | called by muse, mutect2, varscan2
